Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7467, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7467-01A (Primary Tumor).

Pathology Report

Microscopic Discussion:

Sections demonstrate a mildly to moderately hypercellular diffuse glioma involving both the gray and white matter. In contrast to the usual diffuse glial tumor, gray matter involvement predominates. Tumor cells have enlarged round to oval nuclei and most have perinuclear halos. Atypia is mild to moderate. The gray matter shows secondary structures including striking perineuronal satellitosis as well as subpial condensation and foci of perivascular accumulation. No mitotic figures are identified.

Addendum Discussion:

Scattered MIB-1 reactive cells are present throughout the specimen. Because of the unusual growth pattern with numerous admixed neurons, a precise labeling index cannot be determined. However, it appears that greater than 5% of the tumor nuclei are positive. Whereas this does not by itself warrant classification of anaplastic grade 3, it is worrisome and does merit close follow-up.

Final Addendum Diagnosis:

Brain Tumor, Biopsy and resection:
Oligodendroglioma, WHO grade II
MIB-1 labeling index + greater than or equal to 5%

Source: NCI Genomic Data Commons file 15eba653-b395-425e-8a64-92491f9beba9 (TCGA-HT-7467.440FCE7D-5D39-4E81-8B2D-11726CBD3481.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).